Somatic mutation profile of tumor specimen TCGA-KM-8477-01A (aliquot TCGA-KM-8477-01A-11D-2310-10) from TCGA case TCGA-KM-8477, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 56.1 years (20,491 days).
Specimen TCGA-KM-8477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 155ab7d4-662a-473a-85e7-811176f1d98c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KM-8477-10A (Blood Derived Normal), aliquot TCGA-KM-8477-10A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6097d1dd-6afc-46f0-a1b2-6dac792562cd

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 11, Silent 9, Splice Region 2, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIC1 | c.994+1G>A p.X332_splice | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99948304; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 14/140 reads (10%) | catalogued as rs771531141; called by mutect2, varscan2
- PCGF3 | c.262+8T>G | Splice Region (SNP) | VAF 12/80 reads (15%) | catalogued as rs538148298; called by muse, mutect2, varscan2
- RBM10 | c.1693+1G>A p.X565_splice | Splice Site (SNP) | VAF 28/36 reads (78%) | catalogued as COSV61307776, COSV61307835, COSV61309060; called by muse, mutect2, varscan2
- SARM1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV99135083; called by muse, mutect2
- SOS2 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99366952; called by muse, mutect2
- VAMP1 | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs1469664316, COSV99869679; called by muse, mutect2
- AHCYL2 | c.756G>T p.Q252H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CTNNBL1 | c.1324dup p.M442Nfs*6 | Frame Shift Ins (INS) | VAF 37/120 reads (31%) | called by mutect2, pindel, varscan2
- GTF2H4 | c.773T>A p.L258Q | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.214); called by muse, mutect2
- MYPN | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR3C | c.1453C>A p.Q485K | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PTPN3 | c.206_207del p.Y69Ffs*6 | Frame Shift Del (DEL) | VAF 17/129 reads (13%) | called by pindel, varscan2
- SORL1 | c.3366G>C p.Q1122H | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TET1 | c.4573A>G p.I1525V | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLE4 | c.252+4del | Splice Region (DEL) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- TMEM151B | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- WNT5B | c.276G>A p.W92* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- ZNF136 | c.136A>C p.K46Q | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DNAH6 | c.8025G>T p.L2675= | Silent (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- FOLR2 | c.723C>T p.L241= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV99995408; called by muse, mutect2, varscan2
- LRRTM2 | c.774A>C p.L258= | Silent (SNP) | VAF 76/204 reads (37%) | called by muse, mutect2, varscan2
- NCALD | c.438G>A p.E146= | Silent (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- NTSR1 | c.765G>T p.L255= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, varscan2
- OR5F1 | c.81C>T p.L27= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV99558590; called by muse, mutect2, varscan2
- PTPRE | c.912C>T p.F304= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs759996717, COSV54548413; called by muse, mutect2, varscan2
- SEC24C | c.393G>A p.P131= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs375764899; called by muse, mutect2, varscan2
- SLC7A10 | c.918C>T p.F306= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs778074093, COSV53504150; called by muse, varscan2
